Somatic mutation profile of tumor specimen TCGA-66-2800-01A (aliquot TCGA-66-2800-01A-01D-1267-08) from TCGA case TCGA-66-2800, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 70.7 years (25,810 days).
Specimen TCGA-66-2800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9005ca63-373f-4e28-9e2a-caebbd3eb834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2800-11A (Solid Tissue Normal), aliquot TCGA-66-2800-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7305b8fd-8101-4a04-bb0d-cafc61ab6395

The open-access MAF lists 207 somatic variants for this specimen: 152 protein-altering or splice-affecting, 49 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 49, Nonsense Mutation 14, Splice Site 5, Frame Shift Del 3, RNA 3, Splice Region 2, Frame Shift Ins 2, 5'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 36/116 reads (31%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 91/160 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1694C>G p.A565G (on ENST00000404938 / NM_001163941.2; = p.A120G on NM_178559.6) | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV51719318; called by muse, mutect2
- AC127029.3 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 80/750 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV60111882; called by muse, varscan2
- ACSS3 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV54099959; called by muse, mutect2, varscan2
- ADCY2 | c.3191A>G p.N1064S | Missense Mutation (SNP) | VAF 129/274 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV57896110; called by muse, mutect2, varscan2
- ALG2 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53060714; called by muse, mutect2, varscan2
- ALPK2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs565612566, COSV64490186; called by muse, mutect2, varscan2
- AMOTL1 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58570170; called by muse, mutect2, varscan2
- ANGPT4 | c.835+1G>T p.X279_splice | Splice Site (SNP) | VAF 44/113 reads (39%) | catalogued as COSV67922673; called by muse, mutect2, varscan2
- APC | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as CD011074, COSV57377149; called by muse, mutect2
- ARHGEF10 | c.3226A>T p.M1076L (on ENST00000398564; = p.M1051L on NM_014629.4) | Missense Mutation (SNP) | VAF 132/207 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV50673192; called by muse, mutect2, varscan2
- ASB1 | c.330A>C p.K110N | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52828123; called by muse, mutect2
- ATM | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53770558; called by muse, mutect2, varscan2
- ATP6V1A | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56364270; called by muse, mutect2, varscan2
- ATP8B2 | c.2602G>T p.E868* (on ENST00000672630; = p.E835* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 588/901 reads (65%) | catalogued as COSV59248485; called by muse, varscan2
- BEX3 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 216/346 reads (62%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.99); catalogued as COSV55421725; called by muse, mutect2, varscan2
- BROX | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61799882; called by muse, mutect2, varscan2
- C2CD3 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0.113); catalogued as COSV58089270; called by muse, mutect2, varscan2
- C2CD5 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 94/155 reads (61%) | catalogued as COSV61727273; called by muse, mutect2, varscan2
- CACNA1I | c.4945G>A p.E1649K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.824); catalogued as rs761593460, COSV60815780, COSV60817467; called by muse, mutect2, varscan2
- CCDC178 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV55794330; called by muse, varscan2
- CDADC1 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 141/266 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs976194726, COSV51913459, COSV99212537; called by muse, mutect2, varscan2
- CDR1 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 7/262 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.841); catalogued as COSV65164593, COSV65164729; called by muse, mutect2
- CHEK1 | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV54025422; called by muse, mutect2, varscan2
- CLDN25 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71620478; called by muse, mutect2, varscan2
- CNOT2 | c.869A>C p.D290A | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV57506395; called by muse, mutect2, varscan2
- CNTROB | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV58051067; called by muse, mutect2
- CNTROB | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 60/823 reads (7%) | catalogued as COSV66609356; called by muse, mutect2
- COL5A3 | c.5218C>T p.P1740S | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1403555440, COSV53418112; called by muse, mutect2, varscan2
- CRACR2A | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 9/172 reads (5%) | catalogued as rs1424392031, COSV52917770; called by muse, mutect2
- CRYGA | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs773733603, COSV58017835, COSV58018857; called by muse, mutect2
- CSMD3 | c.9044C>T p.S3015F (on ENST00000297405 / NM_001363185.1; = p.S2846F on NM_052900.3) | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52299057, COSV99833420; called by muse, mutect2, varscan2
- CUBN | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64725516; called by muse, mutect2, varscan2
- CWC22 | c.1882A>G p.I628V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1156425982, COSV55431974; called by muse, mutect2, varscan2
- EPB41L3 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 181/467 reads (39%) | catalogued as COSV59443261; called by muse, mutect2, varscan2
- ERC2 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 35/458 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs746883356, COSV55657818; called by muse, mutect2
- ESCO2 | c.1263G>A p.V421= | Splice Region (SNP) | VAF 47/101 reads (47%) | catalogued as rs757245032, COSV100533283, COSV59416287; called by muse, mutect2, varscan2
- FAM135B | c.3865C>G p.R1289G | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52749802, COSV99418979, COSV99424084; called by muse, mutect2, varscan2
- FGF5 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 271/364 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891732; called by muse, mutect2, varscan2
- FN1 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 86/170 reads (51%) | catalogued as COSV60562509; called by muse, mutect2, varscan2
- FSHR | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV58633511; called by muse, mutect2, varscan2
- FSIP2 | c.19219G>A p.E6407K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as COSV100553397; called by muse, mutect2, varscan2
- FUT10 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV104404375, COSV59660275; called by muse, mutect2, varscan2
- GABPB2 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64461493; called by muse, mutect2, varscan2
- GDPD4 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 229/425 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758515411, COSV60017283, COSV60022331; called by muse, mutect2, varscan2
- GLI3 | c.3618G>T p.R1206S | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV67894273; called by muse, varscan2
- GLRA2 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54346959; called by muse, mutect2, varscan2
- GP2 | c.1046G>A p.G349E (on ENST00000381362 / NM_001007240.3; = p.G346E on NM_001502.4) | Missense Mutation (SNP) | VAF 201/382 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56893615; called by muse, mutect2, varscan2
- GPBP1 | c.1356A>T p.K452N | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs747189205, COSV53314146; called by muse, mutect2, varscan2
- GRIN2A | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs775591257, COSV58054538; called by muse, mutect2, varscan2
- HAUS8 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 47/151 reads (31%) | catalogued as COSV53727274; called by muse, mutect2, varscan2
- HSPB8 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56139209; called by muse, mutect2, varscan2
- HTR2A | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 72/121 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV66328320; called by muse, mutect2, varscan2
- HUWE1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0.097); catalogued as COSV53361924; called by muse, mutect2, varscan2
- IFNA16 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV66510580; called by muse, mutect2, varscan2
- IFT52 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV65976002; called by muse, mutect2, varscan2
- IGDCC3 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1201380354, COSV60079755; called by muse, mutect2, varscan2
- ITPK1 | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV50899485; called by muse, mutect2, varscan2
- IVL | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 122/270 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.146); catalogued as COSV100908127, COSV64215646; called by muse, mutect2, varscan2
- KAZN | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV65724798; called by muse, mutect2, varscan2
- KCNH8 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 116/176 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV60474763; called by muse, varscan2
- KL | c.2458G>C p.D820H | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV66309906; called by muse, mutect2, varscan2
- KRBA1 | c.3025G>C p.V1009L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.995); catalogued as COSV55443951; called by muse, mutect2, varscan2
- KRT9 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as COSV55855141, COSV99879403; called by muse, mutect2, varscan2
- LAMA3 | c.9032A>T p.Q3011L (on ENST00000313654 / NM_198129.4; = p.Q1402L on NM_000227.6) | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1300369214, COSV52542207; called by muse, mutect2, varscan2
- LCT | c.4464G>A p.Q1488= | Splice Region (SNP) | VAF 51/123 reads (41%) | catalogued as COSV51556536; called by muse, mutect2, varscan2
- LTK | c.1148A>G p.H383R | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53029162; called by muse, mutect2, varscan2
- MAGEC1 | c.3371C>A p.S1124* | Nonsense Mutation (SNP) | VAF 145/200 reads (73%) | catalogued as COSV53576803, COSV53580170; called by muse, mutect2, varscan2
- MAN1A1 | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs140726044, COSV63784556; called by muse, mutect2, varscan2
- MAP3K5 | c.2564C>G p.P855R | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62891900; called by muse, mutect2, varscan2
- MAP7D2 | c.1835A>G p.D612G | Missense Mutation (SNP) | VAF 111/164 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV65529816; called by muse, mutect2, varscan2
- MAP7D2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs776431196, COSV65529826; called by muse, mutect2, varscan2
- MCC | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.644); catalogued as COSV68729788; called by muse, mutect2
- METTL16 | c.1379C>G p.P460R | Missense Mutation (SNP) | VAF 209/536 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.416); catalogued as COSV54013085, COSV54015944; called by muse, mutect2, varscan2
- MFSD2B | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV57856097; called by muse, mutect2, varscan2
- MIB1 | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.893); catalogued as COSV55094396; called by muse, mutect2, varscan2
- MUC16 | c.24437C>A p.P8146H | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV67471772; called by muse, mutect2
- NCOR1 | c.2602G>T p.A868S | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV51993520; called by muse, mutect2, varscan2
- NIBAN3 | c.529A>T p.T177S | Missense Mutation (SNP) | VAF 166/493 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as COSV56313449; called by muse, mutect2, varscan2
- NUMA1 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 152/802 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61190439; called by muse, mutect2, varscan2
- NUP107 | c.2031G>T p.W677C | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57493665; called by muse, mutect2, varscan2
- ODAM | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 136/967 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV68573398; called by muse, mutect2, varscan2
- OGFR | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs1045444438, COSV51702401; called by muse, mutect2
- ONECUT2 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs572113702, COSV72153224; called by muse, mutect2, varscan2
- OR11H6 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 170/503 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV59644973; called by muse, mutect2, varscan2
- OR4C12 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV58860966; called by muse, mutect2, varscan2
- OR8J3 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56883841; called by muse, mutect2, varscan2
- OTOF | c.361A>C p.T121P | Missense Mutation (SNP) | VAF 123/310 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV55517096; called by muse, mutect2, varscan2
- PASK | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs773924956, COSV52159411; called by muse, mutect2
- PCDH12 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51524189; called by muse, mutect2, varscan2
- PCDHA2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.155); catalogued as rs781948718, COSV65370661; called by muse, mutect2
- PDCD10 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV67103114; called by muse, mutect2, varscan2
- PDE12 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 100/372 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs978437808, COSV60819195; called by muse, mutect2, varscan2
- PDE4DIP | c.3113G>C p.G1038A | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782739764, COSV57725329; called by muse, mutect2, varscan2
- PIAS4 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 121/325 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV53680949; called by muse, mutect2, varscan2
- PIK3C2B | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773548781, COSV65803579, COSV65804043; called by muse, mutect2, varscan2
- PKHD1 | c.6667G>T p.V2223L | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs1448595607, COSV61892262; called by muse, mutect2, varscan2
- PKHD1 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as COSV61892276; called by muse, mutect2, varscan2
- PNPLA5 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV53376194, COSV99336599; called by muse, mutect2, varscan2
- PREX1 | c.1372A>C p.S458R | Missense Mutation (SNP) | VAF 241/770 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV64256112; called by muse, mutect2, varscan2
- PRODH2 | c.397C>A p.L133M (on ENST00000301175; = p.L57M on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.921); catalogued as rs150476704, COSV56561854; called by muse, mutect2, varscan2
- PROM1 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs777502067, COSV71699933; called by muse, mutect2, varscan2
- PSMD3 | c.1476+1G>A p.X492_splice | Splice Site (SNP) | VAF 14/469 reads (3%) | catalogued as COSV52856832, COSV52859570; called by muse, mutect2
- QSOX1 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62581508; called by muse, mutect2, varscan2
- RAI2 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 246/362 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58966027; called by muse, varscan2
- RALB | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV55603726, COSV55604742; called by muse, mutect2, varscan2
- RDH8 | c.505G>T p.V169F (on ENST00000651512; = p.V149F on NM_015725.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV50677916; called by muse, mutect2, varscan2
- RPA1 | c.1507T>C p.C503R | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54613130; called by muse, mutect2, varscan2
- RYR3 | c.14174C>A p.A4725E (on ENST00000389232; = p.A4726E on NM_001036.6) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66806342; called by muse, mutect2
- SAMD9L | c.3685G>C p.V1229L | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs372780313; called by muse, mutect2, varscan2
- SCN4A | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71128822; called by muse, mutect2, varscan2
- SEZ6L | c.2408-2A>C p.X803_splice | Splice Site (SNP) | VAF 77/234 reads (33%) | catalogued as COSV50682225; called by muse, mutect2, varscan2
- SGK3 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61896538; called by muse, mutect2, varscan2
- SGPL1 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV54737675; called by muse, mutect2, varscan2
- SH3TC1 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV55289088; called by muse, mutect2, varscan2
- SIGLEC11 | c.1266G>C p.E422D | Missense Mutation (SNP) | VAF 130/208 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV70222025, COSV70222129; called by muse, varscan2
- SLC36A4 | c.1272C>G p.S424R | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58397523; called by muse, mutect2, varscan2
- SLC5A1 | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 511/1220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56688600; called by muse, mutect2, varscan2
- SLC7A13 | c.1140G>T p.R380S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52536897; called by muse, mutect2, varscan2
- SLMAP | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV55852509; called by muse, mutect2, varscan2
- SPATA4 | c.608T>C p.M203T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV54591560; called by muse, mutect2, varscan2
- SPICE1 | c.1973C>G p.T658R | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV55624396; called by muse, mutect2, varscan2
- STK16 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs966617527, COSV50281816; called by muse, mutect2, varscan2
- STK26 | c.1026+2T>C p.X342_splice | Splice Site (SNP) | VAF 34/47 reads (72%) | catalogued as COSV53748416; called by muse, mutect2, varscan2
- TAS2R38 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV71885987; called by muse, mutect2
- TBC1D5 | c.1340C>G p.A447G | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV53768998; called by muse, mutect2, varscan2
- TBC1D8 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753031086, COSV65216121; called by muse, mutect2, varscan2
- TBX20 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 32/110 reads (29%) | catalogued as COSV101282336, COSV68785565; called by muse, mutect2, varscan2
- TF | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 191/606 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs752357330, COSV53923734; called by muse, mutect2, varscan2
- TIAM1 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 33/565 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as COSV54571642, COSV99737284; called by muse, mutect2
- TRERF1 | c.2662G>T p.D888Y | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61674456; called by muse, mutect2, varscan2
- USH2A | c.6187G>T p.V2063L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56400957; called by muse, mutect2, varscan2
- VWA3B | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV68246188; called by muse, mutect2, varscan2
- XDH | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65150927; called by muse, mutect2, varscan2
- ZAN | c.4244C>A p.P1415H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV61815242; called by muse, mutect2, varscan2
- ZIM2 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 100/185 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55645364; called by muse, mutect2, varscan2
- ZNF326 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1308676620, COSV61036297; called by muse, mutect2, varscan2
- ZNF382 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV53091702; called by muse, mutect2, varscan2
- ZNF639 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58382981, COSV58384232; called by muse, mutect2, varscan2
- ZNF655 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53160025; called by muse, mutect2, varscan2
- ZNF84 | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 179/312 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.623); catalogued as rs1398529541; called by muse, mutect2, varscan2
- ZSCAN25 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 171/475 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV53554383; called by muse, mutect2, varscan2
- ZSCAN31 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs768472174, COSV60181611; called by muse, mutect2, varscan2
- ZSWIM2 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 91/172 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54578986; called by muse, mutect2, varscan2
- ACAT2 | c.449del p.G150Vfs*18 | Frame Shift Del (DEL) | VAF 24/143 reads (17%) | called by mutect2, pindel, varscan2
- GAS7 | c.826del p.A276Pfs*3 (on ENST00000432992 / NM_201433.2; = p.A136Pfs*3 on NM_003644.3) | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 134/1144 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGKV1-12 | c.213T>A p.Y71* | Nonsense Mutation (SNP) | VAF 67/473 reads (14%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 145/515 reads (28%) | called by muse, mutect2, varscan2
- PMCH | c.168dup p.S57Ifs*11 | Frame Shift Ins (INS) | VAF 32/78 reads (41%) | called by mutect2, pindel, varscan2
- SRRM2 | c.6684_6706del p.A2229Cfs*22 | Frame Shift Del (DEL) | VAF 12/153 reads (8%) | called by mutect2, pindel
- AC098582.1 | c.1908G>T p.G636= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV52024076; called by muse, mutect2, varscan2
- ADCY8 | c.607C>T p.L203= | Silent (SNP) | VAF 72/204 reads (35%) | catalogued as COSV53924436; called by muse, mutect2, varscan2
- AMER2 | c.369G>T p.P123= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV63440017; called by muse, mutect2, varscan2
- ASPH | c.2091G>A p.K697= | Silent (SNP) | VAF 96/245 reads (39%) | catalogued as COSV65247113; called by muse, mutect2, varscan2
- ATP6V1A | c.1260A>C p.P420= | Silent (SNP) | VAF 64/105 reads (61%) | catalogued as COSV56364262; called by muse, mutect2, varscan2
- BAZ1A | c.624A>G p.K208= | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as COSV62412002; called by muse, mutect2, varscan2
- BEX3 | c.177G>C p.G59= | Silent (SNP) | VAF 218/347 reads (63%) | catalogued as COSV55421358; called by muse, mutect2, varscan2
- C4orf19 | c.579C>A p.G193= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV52650187; called by muse, mutect2, varscan2
- C8B | c.1626C>T p.T542= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs781205603, COSV64779231; called by muse, mutect2, varscan2
- CACNA1C | c.303C>A p.P101= | Silent (SNP) | VAF 65/87 reads (75%) | catalogued as COSV59763678, COSV59768408; called by muse, mutect2, varscan2
- CD177 | c.627G>T p.L209= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV65122507, COSV65122527; called by muse, mutect2, varscan2
- DCAF4L1 | c.1062C>A p.S354= | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as COSV60788424; called by muse, mutect2, varscan2
- DENND2B | c.1137C>T p.S379= | Silent (SNP) | VAF 14/273 reads (5%) | catalogued as COSV58207448; called by muse, mutect2
- FCSK | c.1155G>A p.Q385= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV55374903; called by muse, mutect2
- FGF13 | c.264C>G p.T88= | Silent (SNP) | VAF 154/221 reads (70%) | catalogued as COSV59549723; called by muse, mutect2, varscan2
- GPRC5A | c.90C>T p.V30= | Silent (SNP) | VAF 154/221 reads (70%) | catalogued as COSV50008611; called by muse, mutect2, varscan2
- HNRNPL | c.1230G>A p.E410= | Silent (SNP) | VAF 14/419 reads (3%) | catalogued as COSV55495239; called by muse, mutect2
- KIF14 | c.2526G>T p.G842= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV66263824; called by muse, mutect2, varscan2
- KLHL11 | c.468C>A p.A156= | Silent (SNP) | VAF 48/111 reads (43%) | catalogued as COSV59863011; called by muse, mutect2, varscan2
- LRRC3B | c.189T>A p.P63= | Silent (SNP) | VAF 68/117 reads (58%) | catalogued as COSV67522504; called by muse, mutect2, varscan2
- LYZL1 | c.60A>T p.A20= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV64966864; called by muse, mutect2, varscan2
- MEP1A | c.2046C>T p.D682= | Silent (SNP) | VAF 266/301 reads (88%) | catalogued as rs762700833, COSV57922291; called by muse, mutect2, varscan2
- NALCN | c.2868A>T p.V956= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV51961473; called by muse, mutect2, varscan2
- NCR3 | c.594C>T p.V198= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV53002366; called by muse, varscan2
- NRXN2 | c.1788T>C p.D596= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as COSV55454038; called by muse, mutect2, varscan2
- OR10H1 | c.651C>A p.L217= | Silent (SNP) | VAF 97/291 reads (33%) | catalogued as rs1290767653, COSV58472811; called by muse, mutect2, varscan2
- OR51I2 | c.900C>A p.R300= | Silent (SNP) | VAF 110/235 reads (47%) | catalogued as COSV58300150; called by muse, mutect2, varscan2
- OR5M1 | c.396C>T p.Y132= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV73202381; called by muse, mutect2, varscan2
- OTULIN | c.312G>T p.T104= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV52506976; called by muse, mutect2, varscan2
- PCDHA6 | c.2193G>T p.A731= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs536478075, COSV65341617, COSV65346997; called by muse, mutect2, varscan2
- PIGV | c.1170G>T p.L390= | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as COSV50301417; called by muse, mutect2
- PIK3CG | c.2235C>A p.V745= | Silent (SNP) | VAF 71/177 reads (40%) | catalogued as COSV63252730; called by muse, mutect2, varscan2
- RPS6KA6 | c.2233C>T p.L745= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1319848303, COSV53124284; called by muse, mutect2, varscan2
- RSPH14 | c.306C>T p.Y102= | Silent (SNP) | VAF 81/197 reads (41%) | catalogued as rs532637699, COSV53271680; called by muse, mutect2, varscan2
- RYR2 | c.12177G>A p.T4059= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1311120147, COSV63710124; ClinVar: likely benign; called by muse, mutect2, varscan2
- SENP7 | c.942A>G p.Q314= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58617894; called by muse, mutect2, varscan2
- SGO1 | c.306A>G p.K102= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV55424995; called by muse, mutect2
- SHISA3 | c.324G>T p.A108= | Silent (SNP) | VAF 151/472 reads (32%) | catalogued as rs1226088667, COSV59980471, COSV59980511; called by muse, varscan2
- SIM1 | c.1764C>A p.P588= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as COSV53496105; called by muse, mutect2, varscan2
- SNAI2 | c.426G>A p.G142= | Silent (SNP) | VAF 182/479 reads (38%) | catalogued as COSV50080059; called by muse, mutect2, varscan2
- SP3 | c.498C>T p.S166= | Silent (SNP) | VAF 341/617 reads (55%) | catalogued as COSV59470635; called by muse, mutect2
- SPDYE1 | c.24C>A p.A8= | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as COSV99323793; called by muse, mutect2, varscan2
- SYMPK | c.3093C>T p.Y1031= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs750400767, COSV55574983; called by muse, mutect2, varscan2
- TCF21 | c.360G>T p.T120= | Silent (SNP) | VAF 151/355 reads (43%) | catalogued as COSV52819568; called by muse, mutect2, varscan2
- TNN | c.2769C>T p.D923= | Silent (SNP) | VAF 37/188 reads (20%) | catalogued as rs199534795; called by muse, mutect2, varscan2
- VEZF1 | c.1551A>G p.T517= | Silent (SNP) | VAF 72/210 reads (34%) | catalogued as COSV51970058; called by muse, mutect2, varscan2
- WIPF3 | c.1272G>A p.T424= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs571269176, COSV54212327; called by muse, mutect2, varscan2
- ZFAT | c.1965G>T p.G655= | Silent (SNP) | VAF 76/215 reads (35%) | catalogued as COSV64745443; called by mutect2, varscan2
- ZNF446 | c.880T>C p.L294= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, varscan2
- CHD1L | c.-2C>A | 5'UTR (SNP) | VAF 15/23 reads (65%) | catalogued as rs782474002, COSV100787243; called by muse, mutect2, varscan2
- DST | c.4297-2735G>T | Intron (SNP) | VAF 151/399 reads (38%) | catalogued as COSV99749006; called by muse, mutect2, varscan2
- ECPAS | chr9:111484443 G>A | 5'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as COSV52206139; called by muse, mutect2, varscan2
- HMGN2P46 | n.1078C>A | RNA (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- MIR380 | n.27T>C | RNA (SNP) | VAF 17/22 reads (77%) | catalogued as rs764740283; called by muse, mutect2, varscan2
- ZNF271P | n.1161del | RNA (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
